Surgical pathology report (de-identified scan), TCGA case TCGA-V4-A9ET, project TCGA-UVM (Uveal Melanoma), tissue source site Institut Curie, specimen TCGA-V4-A9ET-01A (Primary Tumor).

[page 1 of 2]
ICD O-3

Melanoma, epithelioid & spindle
cell mixed 8770/3

Site ^{C69.3} Choroid

~~ret~~ Uveal tract C69.4

MS 2/16/14

Enucleation of the right eye

Macroscopy

The eyeball measures 26 mm in diameter with a segment of optic nerve of 5 mm. At the section, a tumor located at the inferior part of the eyeball and measuring 18 mm is observed. Tissue specimens are taken for cryopreservation prior fixation.

Microscopy

See path discrepancy form for
epithelioid and spindle cell ratio.

The tumor observed macroscopically presents the histological aspect of an uveal melanoma. This tumor is composed of epithelioid (50%) and of fusiform cells (50%). The cell atypias are severe. Presence of melanin. The mitotic activity is low (2 mitoses per 10 HPF). There is a focal infiltration of the ciliary body and of the inner part of the sclera, on a thickness of about 1 mm. The tumor is at distance from the optic nerve which is free on its entire course. The cut end of the optic nerve and the meningeal sheath are also free of tumor.

Conclusion

Uveal melanoma composed of epithelioid and of fusiform cells.

Tumor size: 18X10 mm main lines.

Mitotic activity: low

Focal tumor infiltration of the ciliary body and of the 1/3 inner part of the sclera, on a space of about 1 mm, without extra-scleral extension.

Optic nerve on its entire course, optic nerve cut end and meningeal sheaths free of tumor.

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	50% epithelioid cells 50% spindle cells	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	61-90% spindle cells 1-30% epithelioid cells	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	The section of the frozen sample used for sending to TCGA corresponds to a section of the tumor where the epithelioid part is predominant. The percentages mentioned on the initial Pathology Report correspond to an average on the whole embedded sections used for establish the Pathology Report.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file c5313bfc-6f2b-422a-9e56-8deb23cbdb1a (TCGA-V4-A9ET.7D7514B8-A5CE-48D5-8B83-BC06F1718696.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).